Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PR, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PR-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Kidney, left, partial nephrectomy:
1. Papillary renal cell carcinoma, two foci measuring 5.0 and 2.2 cm; see comment.
2. Adrenal gland with no tumor.
- B. Soft tissue, peri-nephric, resection: Fibroadipose tissue with no tumor.

COMMENT:

Kidney Tumor Synoptic Comment

- **Histologic type:** Renal cell carcinoma, papillary type II (tumor #1) and type I (tumor #2).
- **Grade:** Fuhrman grading for RCC: Grade 3 (tumor #1), grade 2 (tumor #2).
- **Maximum tumor diameter:** 5.0 cm (tumor #1), 2.2 cm (tumor #2).
- **Site within kidney:** Upper pole.
- **Renal pelvis:** Not present.
- **Ureter:** Not present.
- **Renal sinus:** Not present.
- **Hilar renal veins:** Not present.
- **Intrarenal veins and lymphatics:** Not identified.
- **Adrenal gland:** Normal.
- **Capsule/perirenal fat:** Tumor does not penetrate capsule.
- **Hilar lymph nodes:** 0/0.
- **Resection margins:** Negative.
- **Proximity to nearest margin:** <0.05 cm (tumor #1) and 0.15 cm (tumor #2) from renal parenchyma margin. 0.2 cm (tumor #1) from radial fat margin.
- **Stage:** pT1bNXMX.
- **Additional comments:** None.

ICD-O-3
Carcinoma, papillary renal cell
Site: @ Kidney NOS 8260/3
C64.9
JWB/30/14

Specimen(s) Received

- A: Left renal mass (fresh)
B: Peri nephric fat

[page 2 of 2]
Clinical History

The patient is an [REDACTED] year-old man with history of papillary renal cell carcinoma, status post right partial nephrectomy in [REDACTED]. On imaging, he has a 4-cm complex left upper pole renal mass with an adjacent 2-cm solid mass. He undergoes left partial nephrectomy.

Gross Description

The specimen is received in two parts, each labeled with the patient's name and unit number.

Part A is received in formalin and is additionally labeled "#1 left renal mass." It consists of a single irregular partial kidney resection with attached perinephric fat, weighing 297 gm and measuring 28 x 9 x 5 cm. The kidney segment measures 8 x 5 x 4.5 cm. There are two tumors present in the specimen. Tumor #1 measures 5 x 3.5 x 4 cm and is gold, friable, irregular, and hemorrhagic. Tumor #2 measures 2.2 x 2 x 1.6 cm and is yellow, solid, and abuts tumor #1. The tumors appear grossly encapsulated with a thin shell of kidney parenchyma attached. There is one area of possible partial disruption of the capsule near the kidney parenchyma for tumor #1. An adrenal gland is identified, which is orange-tan and measures 4.5 x 3.4 x 1.2 cm. There is no gross involvement of the tumor with the adrenal gland, and it is roughly 1.3 cm away from the gland. There is no sinus or hilus found in the specimen. The renal parenchyma resection margin is inked black, and the perinephric margin is inked blue. No candidate lymph nodes are identified. A portion of tumor #2 is taken for tissue banking.

Representative sections are submitted as follows:

Cassette A1: Tumor #1, relationship to kidney parenchyma.
Cassettes A2-A4: Tumor #1, relationship to perinephric fat margin.
Cassette A5: Tumor #2, relationship to kidney parenchyma.
Cassette A6: Tumor #2, relationship to perinephric fat margin.
Cassette A7: Tumor #1, relationship to adrenal gland.
Cassette A8: Adrenal gland.
Cassette A9-A11: Additional sections of the kidney with tumor.

Part B, received in formalin and labeled "perinephric fat," consists of multiple soft irregular pieces of yellow fatty tissue measuring 10 x 8 x 1.5 cm in aggregate. Visual inspection, palpation, and serially sectioned reveal no lesions or nodules. Uniformly soft yellow fat is seen. Representative sections are submitted in cassette B1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED] Pathology Resident

[REDACTED] Pathologist
Electronically signed out on [REDACTED]

Criteria	Dr 11/6/14	Yes	No

Source: NCI Genomic Data Commons file d78fe0de-9cfe-460e-a12e-903c89710062 (TCGA-UZ-A9PR.2A4F65D3-E77B-4ABB-BB03-6C5EA0EE75F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).